FM case AD4529 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/14a67e95-c866-4cd7-968e-09a1b926eeba

Female, 24.2 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
